Gene-level copy-number profile of tumor specimen HCM-SANG-0294-C15-01A from HCMI case HCM-SANG-0294-C15, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Esophagus, NOS; Tumor grade: G3.
Specimen HCM-SANG-0294-C15-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 34087c99-831e-4c10-aa6d-7f7be548bd28.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-SANG-0294-C15-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,709 have no estimate.
https://portal.gdc.cancer.gov/files/b9d90dff-84b7-45f2-9e55-1d1382620692

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 627; copy number 1: 6,916; copy number 2: 43,610; copy number 3: 5,988; copy number 4: 1,742; copy number 7: 1; copy number 10: 30.

Homozygous deletions (total copy number 0; autosomes only): 114 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:12,838,125–12,841,357, 1 gene: PRAMEF30P.
- chr1:12,857,086–12,861,909, 1 gene (within-gene range 0–2): PRAMEF2.
- chr12:56,923,133–56,959,374, 3 genes: SDR9C7, AC026120.2, RDH16.
- chr21:13,038,160–16,873,691, 85 genes (broad region; genes not listed).
- chr21:22,205,192–24,547,942, 24 genes: RNU4-45P, AP000561.1, MAPK6P2, AP000959.1, AP000949.1, AP001116.1, MIR6130, ZNF299P, MSANTD2P1, AP001255.1, RNU2-55P, D21S2088E, EEF1A1P1, TUBAP1, Y_RNA, AP000459.1, AP000474.2, AP000474.1, AP000477.2, AP000477.3, AP000477.1, AP000470.1, LINC01689, LINC01684.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 31 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:51,993,702–52,017,620, 1 gene, copy number 7: LRRC66.
- chr12:68,746,125–69,823,204, 30 genes, copy number 10 (within-gene range 1–10): SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2, CPM, RNU7-4P, AC025423.5, PRELID2P1, AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP.

Autosomal genes at a single copy (total copy number 1): 6,084. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
